Gene-level copy-number profile of tumor specimen TCGA-AO-A129-01A from TCGA case TCGA-AO-A129, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIB; Age at diagnosis: 29.8 years (10,898 days).
Specimen TCGA-AO-A129-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BRCA.4cd8277c-8a70-44e6-b491-cd35c63408db.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-AO-A129-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 813 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/4f003ba0-143c-4af4-bc46-0d98df248b70

Most common (modal) total copy number across autosomal genes: 5 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 38; copy number 2: 13,096; copy number 3: 9,942; copy number 4: 7,406; copy number 5: 17,430; copy number 6: 4,849; copy number 7: 2,734; copy number 8: 777; copy number 9: 284; copy number 10: 1,342; copy number 11: 255; copy number 12: 775; copy number 13: 636; copy number 15: 36; copy number 16: 41; copy number 19: 39; copy number 20: 123; copy number 24: 7.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-AO-A129-01A-21D-A10L-01): tumor purity 0.53, ploidy 1.87, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 11, i.e. more than twice the modal value of 5; autosomes only): 1,912 genes in 11 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:157,232,231–163,355,764, 235 genes, copy number 12 (broad region; genes not listed).
- chr1:215,622,891–216,423,448, 1 gene, copy number 11 (within-gene range 6–11): USH2A.
- chr1:216,072,465–248,919,946, 740 genes, copy number 11–13 (broad region; genes not listed).
- chr3:187,197,090–188,154,057, 20 genes, copy number 12: AC007920.1, RTP1, MASP1, AC007920.2, RTP4, AC068299.2, AC068299.1, LINC02041, SST, RTP2, AC072022.1, BCL6, AC072022.2, AC108681.1, AC068295.1, LINC01991, AC092941.1, AC092941.2, AC022498.1, LPP-AS2.
- chr3:188,178,543–188,180,812, 1 gene, copy number 12: FLJ42393.
- chr3:191,267,168–196,934,714, 148 genes, copy number 11 (broad region; genes not listed).
- chr6:102,350,271–102,453,792, 2 genes, copy number 11: AL357139.2, AL357139.1.
- chr8:73,064,543–79,314,951, 82 genes, copy number 12 (within-gene range 6–12) (broad region; genes not listed).
- chr8:105,546,089–106,060,524, 1 gene, copy number 12 (within-gene range 9–12): ZFPM2-AS1.
- chr8:105,737,280–138,083,657, 366 genes, copy number 12 (broad region; genes not listed).
- chr10:44,712–18,543,557, 316 genes, copy number 12–24 (within-gene range 10–24) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 38. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
